Gene-level copy-number profile of tumor specimen TCGA-A7-A0CJ-01A from TCGA case TCGA-A7-A0CJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.5 years (21,014 days).
Specimen TCGA-A7-A0CJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.363b439f-0335-48f6-838b-e603c24ff1e3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A0CJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b39500ef-1fc8-4d4e-975a-032dc5a69713

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,662; copy number 2: 12,479; copy number 3: 18,260; copy number 4: 18,054; copy number 5: 4,151; copy number 6: 3,721; copy number 7: 805; copy number 8: 577; copy number 9: 8; copy number 10: 7; copy number 11: 54; copy number 13: 31; copy number 17: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A0CJ-01A-21D-A011-01): tumor purity 0.81, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,486 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:3,126,933–4,467,273, 9 genes, copy number 8 (within-gene range 4–8): TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1.
- chr3:91,356,755–109,977,767, 213 genes, copy number 8 (broad region; genes not listed).
- chr4:58,103,147–58,118,070, 2 genes, copy number 7: SRIP1, AC096725.1.
- chr4:62,816,826–62,818,794, 1 gene, copy number 11: EXOC5P1.
- chr7:143,047,213–148,420,998, 98 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:153,355,365–159,233,377, 92 genes, copy number 8–13 (broad region; genes not listed).
- chr10:81,875,194–84,294,659, 23 genes, copy number 7 (within-gene range 4–7): NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P, RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858.
- chr10:121,478,332–121,615,839, 2 genes, copy number 8: FGFR2, AC009988.1.
- chr10:123,913,574–124,450,048, 8 genes, copy number 8: AC068058.1, BX469938.1, YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1.
- chr10:125,666,875–125,853,695, 11 genes, copy number 8: ALDOAP2, AL158835.1, EDRF1-DT, AL158835.3, AL158835.2, EDRF1, EDRF1-AS1, MMP21, UROS, MIR4484, BCCIP.
- chr11:135,061,781–135,075,908, 1 gene, copy number 9: LINC02684.
- chr13:30,202,630–30,429,758, 9 genes, copy number 7 (within-gene range 2–7): KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5.
- chr16:7,878,799–10,182,928, 41 genes, copy number 7 (within-gene range 3–7): AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3.
- chr18:12,739,490–15,006,352, 75 genes, copy number 8–17 (within-gene range 2–17) (broad region; genes not listed).
- chr18:20,946,906–36,279,119, 253 genes, copy number 7–9 (broad region; genes not listed).
- chr18:36,777,647–44,071,701, 47 genes, copy number 7: TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1, AC083760.1, RNA5SP455.
- chr18:52,223,078–80,247,514, 410 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–28,792,871, 27 genes, copy number 7: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1.
- chr20:1,226,056–4,024,444, 102 genes, copy number 8 (broad region; genes not listed).
- chr20:49,794,811–52,699,472, 62 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 823. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
